Somatic mutation profile of tumor specimen TCGA-YJ-A8SW-01A (aliquot TCGA-YJ-A8SW-01A-11D-A377-08) from TCGA case TCGA-YJ-A8SW, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Prostate gland.
Specimen TCGA-YJ-A8SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8570fc46-88b4-4266-a882-8f4f3b2fde45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YJ-A8SW-10A (Blood Derived Normal), aliquot TCGA-YJ-A8SW-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7285446b-a768-41b6-b549-da71e934c5e1

The open-access MAF lists 58 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs370259792; called by muse, mutect2, varscan2
- ADAMTS6 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.305); catalogued as COSV101125008; called by muse, mutect2, varscan2
- ADGRF5 | c.3529A>T p.I1177F | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99345454; called by muse, mutect2
- ANKRD13A | c.557A>C p.E186A | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as COSV99923934; called by muse, mutect2, varscan2
- B4GALNT4 | c.636+1G>C p.X212_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100327457; called by muse, mutect2, varscan2
- B4GALNT4 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1439473275, COSV100327458; called by muse, mutect2
- DRICH1 | c.572G>C p.C191S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); catalogued as COSV100497430; called by muse, mutect2, varscan2
- EXOC4 | c.1207A>G p.M403V | Missense Mutation (SNP) | VAF 131/242 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99553493; called by muse, mutect2, varscan2
- FAT2 | c.9893C>A p.S3298Y | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55830182; called by muse, mutect2, varscan2
- FOXL1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs1331088417, COSV100206221; called by muse, mutect2, varscan2
- GAL3ST3 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100360822; called by muse, mutect2
- GDNF | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1409646713, COSV58479149; called by muse, mutect2, varscan2
- GGTLC1 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs746514954, COSV53846075; called by muse, mutect2, varscan2
- GINS1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as COSV99320069; called by muse, mutect2, varscan2
- LAMB1 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as COSV99740561; called by muse, mutect2
- LCP2 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs369823137; called by muse, mutect2, varscan2
- LTBP1 | c.2518G>T p.V840L (on ENST00000404816 / NM_206943.4; = p.V514L on NM_000627.4) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV100616968, COSV63199190; called by muse, mutect2, varscan2
- MYH8 | c.5236G>A p.E1746K | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV101238383, COSV99063191; called by muse, mutect2, varscan2
- NCR1 | c.336G>C p.L112F | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99400890; called by muse, mutect2, varscan2
- NR6A1 | c.1106T>C p.I369T (on ENST00000487099 / NM_033334.4; = p.I364T on NM_001489.5) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV100748515; called by muse, mutect2, varscan2
- OPCML | c.918T>A p.N306K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1490717169, COSV100100488; called by muse, mutect2, varscan2
- P4HA3 | c.349A>C p.K117Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.229); catalogued as COSV100525680; called by muse, mutect2
- PGBD1 | c.1808G>T p.G603V | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99460111; called by muse, mutect2, varscan2
- POLI | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs759003923, COSV99471023; called by muse, mutect2, varscan2
- PRSS12 | c.2092C>G p.L698V | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs1017114754, COSV99627927, COSV99628148; called by muse, mutect2
- RESF1 | c.4575G>T p.Q1525H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.195); catalogued as COSV100440297, COSV57025472; called by muse, mutect2, varscan2
- RXRB | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63399763; called by muse, mutect2
- SRP19 | c.47T>C p.I16T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99295298; called by muse, mutect2, varscan2
- STING1 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV100423443; called by muse, mutect2, varscan2
- TMEM87A | c.311A>T p.Y104F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.696); catalogued as COSV100213215; called by muse, mutect2, varscan2
- TNFRSF21 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57281065, COSV57283389; called by muse, mutect2, varscan2
- TRIM28 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.971); catalogued as rs767456825, COSV99448949; called by muse, mutect2, varscan2
- TSC1 | c.3419C>T p.P1140L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs751126355, COSV100051359; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- VWC2 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100514139, COSV61484723; called by mutect2, varscan2
- WAS | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs781917584, CD962186, COSV100939475; called by muse, mutect2, varscan2
- ZNF175 | c.1011C>G p.C337W | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99219435; called by muse, mutect2, varscan2
- ZNF347 | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs1354162407, COSV100498254; called by muse, mutect2, varscan2
- ZNF665 | c.713C>G p.S238* (on ENST00000600412; = p.S303* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 57/251 reads (23%) | catalogued as COSV101128278; called by muse, mutect2, varscan2
- ZNF770 | c.170G>T p.C57F | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100695914; called by muse, mutect2, varscan2
- E2F4 | c.513+1G>A p.X171_splice | Splice Site (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- FTSJ3 | c.1615_1621del p.E539Mfs*38 | Frame Shift Del (DEL) | VAF 78/167 reads (47%) | called by mutect2, pindel, varscan2
- RLIM | c.1585del p.S530Afs*8 | Frame Shift Del (DEL) | VAF 15/15 reads (100%) | called by mutect2, varscan2
- UTP20 | c.1430+1del | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- APC2 | c.1941C>T p.G647= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV99279369; called by muse, mutect2
- CKAP2L | c.486T>C p.C162= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100198572; called by muse, mutect2, varscan2
- GTF2E2 | c.267T>C p.H89= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs746850928, COSV100577098; called by muse, mutect2, varscan2
- LRFN1 | c.1200G>A p.P400= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV99952892; called by muse, mutect2
- MAP2 | c.4152C>T p.D1384= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs571107524, COSV52288764; called by muse, mutect2, varscan2
- OR6B2 | c.48C>T p.G16= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99401392; called by muse, mutect2, varscan2
- PLXDC1 | c.864C>T p.S288= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100195245; called by muse, mutect2
- SPAG6 | c.84G>A p.A28= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100510219; called by muse, mutect2, varscan2
- SPEN | c.8091G>A p.V2697= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs1453931492, COSV101005156, COSV65363379; called by muse, mutect2, varscan2
- SPN | c.546C>A p.T182= | Silent (SNP) | VAF 43/198 reads (22%) | catalogued as COSV100788759; called by muse, mutect2, varscan2
- TRRAP | c.2913G>T p.L971= | Silent (SNP) | VAF 77/154 reads (50%) | catalogued as COSV100722382; called by muse, mutect2, varscan2
- WDR72 | c.162G>A p.A54= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs545775155, COSV64747210; called by muse, mutect2, varscan2
- ZFHX4 | c.7845A>G p.E2615= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs1292170032, COSV99261803; called by muse, mutect2, varscan2
- DCHS2 | n.5050T>C | RNA (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100601643; called by muse, mutect2, varscan2
- HMGCL | c.750+938C>T | Intron (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
